Gene-level copy-number profile of tumor specimen C3N-02144-02 from CPTAC case C3N-02144, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 71.9 years (26,253 days).
Specimen C3N-02144-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 883d4f6c-baf5-4b30-9647-05a35b99b1bd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02144-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/008b1aad-2b5d-4292-a046-63f5c2948828

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 351; copy number 1: 821; copy number 2: 29,301; copy number 3: 18,908; copy number 4: 7,582; copy number 5: 461; copy number 6: 178; copy number 7: 281; copy number 8: 162; copy number 9: 341; copy number 10: 33; copy number 11: 13; copy number 12: 15; copy number 13: 160; copy number 15: 69; copy number 16: 11; copy number 17: 104; copy number 19: 3; copy number 21: 64; copy number 22: 1; copy number 24: 42.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:130,962,588–130,962,668, 1 gene: MIR378C.
- chr13:68,693,804–68,694,081, 1 gene: RN7SL761P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,938 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:57,544,535–58,296,817, 8 genes, copy number 5–6: AC073875.1, ACTG1P22, VRK2, AC068193.1, FANCL, AC007250.1, EIF3FP3, LINC01795.
- chr4:52,590,960–53,366,066, 15 genes, copy number 5 (within-gene range 2–5): USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1.
- chr4:54,229,280–54,298,245, 1 gene, copy number 5 (within-gene range 2–7): PDGFRA.
- chr4:60,750,575–62,220,470, 12 genes, copy number 5: LINC02496, AC105420.1, MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1.
- chr4:130,808,507–131,113,255, 3 genes, copy number 13: AC093831.2, AC093831.1, AC025554.1.
- chr4:137,301,001–150,257,438, 192 genes, copy number 9–24 (broad region; genes not listed).
- chr5:1,005,039–6,496,723, 84 genes, copy number 5–15 (broad region; genes not listed).
- chr5:8,572,047–9,903,852, 28 genes, copy number 5 (within-gene range 4–5): AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221.
- chr5:14,143,342–14,877,919, 15 genes, copy number 5: TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5.
- chr5:25,909,503–27,121,150, 10 genes, copy number 6: MSNP1, RNU4-43P, AC025475.1, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P.
- chr5:30,365,405–30,365,684, 1 gene, copy number 6: AC114300.1.
- chr7:24,698,355–40,099,580, 310 genes, copy number 8–9 (broad region; genes not listed).
- chr7:43,582,758–43,926,411, 7 genes, copy number 7 (within-gene range 3–7): STK17A, COA1, BLVRA, AC005189.1, MRPS24, URGCP-MRPS24, URGCP.
- chr7:63,011,463–63,011,569, 1 gene, copy number 5: RNU6-417P.
- chr8:1,971,153–7,187,316, 71 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:7,298,744–7,355,359, 1 gene, copy number 5 (within-gene range 4–5): FAM66B.
- chr8:7,332,387–7,342,942, 3 genes, copy number 5: USP17L1, USP17L4, AC130360.1.
- chr8:9,555,912–9,782,346, 2 genes, copy number 5 (within-gene range 2–5): TNKS, AC103834.1.
- chr8:9,984,004–12,025,598, 66 genes, copy number 6 (broad region; genes not listed).
- chr8:84,948,585–85,284,073, 11 genes, copy number 9: ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2.
- chr8:86,866,415–89,927,888, 21 genes, copy number 8–13: CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2.
- chr8:95,066,808–106,060,524, 209 genes, copy number 5–15 (within-gene range 3–15) (broad region; genes not listed).
- chr8:132,120,859–135,656,722, 54 genes, copy number 5–7: KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1.
- chr10:27,672,874–28,533,066, 15 genes, copy number 5–7 (within-gene range 3–7): MKX, MKX-AS1, RPL36AP55, AL390866.1, MRPS21P5, MPP7, AL355501.1, MIR8086, MPP7-DT, ZNF101P1, U3, LINC02652, RPSAP10, RN7SKP39, WAC-AS1.
- chr10:31,187,715–33,341,905, 42 genes, copy number 5: LINC02664, ZEB1-AS1, RNA5SP309, ZEB1, SPTLC1P1, AL117340.1, AL161935.1, AL161935.2, MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P, CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1.
- chr11:54,591,480–55,389,472, 22 genes, copy number 6: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15, OR4A9P.
- chr12:752,579–10,454,685, 357 genes, copy number 7–9 (broad region; genes not listed).
- chr12:60,363,822–69,738,574, 188 genes, copy number 5–22 (broad region; genes not listed).
- chr12:84,183,324–84,183,448, 1 gene, copy number 10: AC090679.1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:30,267,553–32,478,250, 169 genes, copy number 5–8 (broad region; genes not listed).
- chr19:27,638,483–27,646,483, 2 genes, copy number 5: ERVK-28, AC112702.1.
- chr20:8,998,849–9,873,900, 8 genes, copy number 8: Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1.
- chr20:22,220,554–22,471,557, 5 genes, copy number 6–7: AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1.

Autosomal genes at a single copy (total copy number 1): 656. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
